Gene-level copy-number profile of tumor specimen TCGA-SI-A71Q-01A from TCGA case TCGA-SI-A71Q, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 34.4 years (12,559 days).
Specimen TCGA-SI-A71Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.89c146f4-b242-4a27-aec9-6807ce85e494.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SI-A71Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7d90778e-3659-4754-8bd3-04fae842b017

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,837; copy number 2: 10,840; copy number 3: 22,078; copy number 4: 19,120; copy number 5: 4,570; copy number 6: 1,104; copy number 7: 243; copy number 8: 3; copy number 15: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SI-A71Q-01A-12D-A33D-01): tumor purity 0.93, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 253 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:182,921,240–184,780,720, 70 genes, copy number 7 (broad region; genes not listed).
- chr7:8,433,609–8,752,961, 1 gene, copy number 7 (within-gene range 5–7): NXPH1.
- chr8:43,493,937–43,674,591, 8 genes, copy number 7: AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr8:54,509,422–54,871,720, 1 gene, copy number 7 (within-gene range 5–7): RP1.
- chr8:54,696,398–57,805,029, 50 genes, copy number 7: AC090151.1, AC084834.1, XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1, TMEM68, RNA5SP265, TGS1, LYN, AC018607.1, SNORA1B, RN7SL798P, RN7SL323P, AC046176.1, RPS20, SNORD54, CERNA3, NPM1P21, MOS, AC107376.1, PLAG1, CHCHD7, AC107952.2, AC107952.1, SDR16C5, SDR16C6P, PENK, AC012349.1, SEPTIN10P1, LINC00968, AC013644.1, RPL37P6, AC009597.1, AC009597.2, RNU6-13P, BPNT2, RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1, RPL30P10, AC068075.2, AC090796.1, AC104051.1, AC104051.2.
- chr8:77,399,072–78,956,082, 13 genes, copy number 7: AC062004.1, AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605.
- chr11:22,445,673–22,625,823, 3 genes, copy number 8: LINC01495, AC055878.1, FANCF.
- chr11:30,231,014–30,850,559, 7 genes, copy number 15 (within-gene range 4–15): FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1.
- chr12:5,531,869–5,946,232, 1 gene, copy number 7 (within-gene range 3–7): ANO2.
- chr12:15,882,387–23,251,499, 99 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,837. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
